Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3726, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3726-01A (Primary Tumor).

Diagnosis:

Resection material from the colon or rectum shows tumor-free resection margins and includes a moderately differentiated adenocarcinoma or rectal carcinoma with incipient infiltration of the perimuscular fatty tissue without regional lymph node metastases (G2, pT3 pN0 0/34) L0 V0 R0).

Source: NCI Genomic Data Commons file 1750cc9d-3cb4-4540-b724-cb87f41505e0 (TCGA-AG-3726.FCB98B32-519D-4BB0-BC1B-36DA86D4320A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).